Gene-level copy-number profile of tumor specimen TCGA-EE-A29L-06A from TCGA case TCGA-EE-A29L, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 79.0 years (28,870 days).
Specimen TCGA-EE-A29L-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.248f8bb1-d192-42c4-9446-b4389c89cd2c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A29L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/52337a51-5543-4ccd-95d5-10955372348d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 352; copy number 2: 12,037; copy number 3: 21,772; copy number 4: 16,275; copy number 5: 6,135; copy number 6: 1,890; copy number 7: 837; copy number 8: 325; copy number 9: 52; copy number 10: 140.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A29L-06A-12D-A194-01): tumor purity 0.97, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,354 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,999,147–85,133,138, 1 gene, copy number 7 (within-gene range 4–7): DNAI3.
- chr1:85,133,794–85,708,433, 16 genes, copy number 7: MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10, AL078459.1, DDAH1, Y_RNA, AL360219.1, AC092807.3, AC092807.2, CCN1, SNORD81, AC092807.1, ZNHIT6.
- chr1:87,620,803–91,644,082, 69 genes, copy number 10 (broad region; genes not listed).
- chr1:92,508,696–92,792,404, 1 gene, copy number 9 (within-gene range 5–9): EVI5.
- chr1:92,647,048–95,782,342, 78 genes, copy number 7–9 (broad region; genes not listed).
- chr1:97,933,474–121,580,524, 479 genes, copy number 7 (broad region; genes not listed).
- chr8:1,565,509–1,801,711, 6 genes, copy number 10 (within-gene range 4–10): DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1.
- chr8:2,726,956–2,926,689, 3 genes, copy number 8 (within-gene range 4–8): AC246817.1, AC115485.1, AC023296.1.
- chr8:3,373,353–3,700,628, 3 genes, copy number 8: AC026991.1, AC026991.2, RNA5SP251.
- chr22:15,290,718–20,151,055, 221 genes, copy number 7 (broad region; genes not listed).
- chr22:24,719,034–30,968,774, 195 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr22:35,501,861–42,343,616, 282 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 352. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
